Somatic mutation profile of tumor specimen TARGET-20-PANSBH-09A (aliquot TARGET-20-PANSBH-09A-01D) from TARGET case TARGET-20-PANSBH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.3 years (491 days).
Specimen TARGET-20-PANSBH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7ac8e90-4598-4e39-be9d-ed0a384989a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANSBH-14A (Bone Marrow Normal), aliquot TARGET-20-PANSBH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b31d6d1-56f7-4aa8-b026-c64bafd531e7

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHACTR4 | c.1028C>T p.P343L (on ENST00000373839 / NM_001350159.2; = p.P353L on NM_023923.4) | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs1029137640, COSV65784921; called by muse, mutect2
